Surgical pathology report (de-identified scan), TCGA case TCGA-06-0133, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0133-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] 06-0133 [REDACTED]

Surgical Pathology Report

[REDACTED]

=====

CLINICAL HISTORY

[REDACTED] has new onset disorientation, facial droop, and speech problems. On imaging has a 3.0 cm. right temporal lobe mass with enhancement, plus two additional lesions in the corpus callosum.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Right temporal (frontal lobe) tumor, resection

PATHOLOGICAL DIAGNOSIS:

Brain, right temporal, excision: Glioblastoma.
See Comment.

COMMENT

The tumor is an astrocytic neoplastic proliferation that diffusely infiltrates and extensively effaces the cerebrum. The neoplasm has nuclear anaplasia, mitotic activity, prominent microvascular cellular proliferation with vascular necrosis and thrombosis, and zones of necrosis, some with pseudopalisading.

Special stains to better characterize the lesion are being requested and will be reported as an addendum.

[REDACTED]

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

[REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled [REDACTED] [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

[REDACTED]

[page 2 of 3]
[REDACTED]

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Interpretation

MIB-1 proliferation index: 25%.
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates fibrillogenesis by the neoplastic cells. A small minority of cells over expresses the p53 protein. With the MIB-1 there is a proliferation index of about 25% in the more active areas.

Comment: The immunophenotype supports a diagnosis of high-grade astrocytic neoplasm.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Right temporal (frontal lobe) tumor, touch preps and smears: High histological grade glioma (C/W GBM, R/O gliosarcoma). [REDACTED]

[REDACTED]

GROSS DESCRIPTION

Received fresh, one fragment of cerebrum, 4.5 x 2.7 x 2.0 cm. Cerebrum, firm, creamy-white cortex, focally glistening and grayish-pink. In total, A1-A5.

[REDACTED]

ICD-9(s):

191.2 191.2

[REDACTED]

Histo Data

Part A: Right temporal (frontal lobe) tumor, resection

[REDACTED]

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

[page 3 of 3]
[REDACTED]

H/E x 1	3	[REDACTED]
H/E x 1	4	[REDACTED]
mGFAP-DA x 1	5	[REDACTED]
H/E x 1	5	[REDACTED]
MGMT x 1	5	[REDACTED]
MIB1-DA x 1	5	[REDACTED]
P53DO7 x 1	5	[REDACTED]

*** End of Report ***

[REDACTED]

Source: NCI Genomic Data Commons file c7b4e592-f909-4b38-af77-3d8608300c4c (TCGA-06-0133.6D9A0D3D-CCBF-4E8D-9EEB-8182F1000F39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).